Somatic mutation profile of tumor specimen BA2359D (aliquot aq-BA2359D) from BEATAML1.0 case 2501, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.9 years (20,787 days).
Specimen BA2359D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 499037c0-0ee3-4eed-9ea3-bd1ee89f03b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2757D (Solid Tissue Normal), aliquot aq-BA2757D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/949976ee-214c-44b7-ac71-ee19a32f2479

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 32/90 reads (36%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- C5orf22 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.203); catalogued as rs771269573; called by muse, mutect2, varscan2
- CHL1 | c.2249C>A p.T750N (on ENST00000397491 / NM_001253387.1; = p.T766N on NM_006614.4) | Missense Mutation (SNP) | VAF 134/252 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs141760963, COSV56598807; called by muse, mutect2
- DNMT3A | c.2635A>G p.N879D | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1188120438, COSV53036758; called by muse, mutect2, varscan2
- DOK6 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as rs747193337, COSV66938786; called by muse, mutect2, varscan2
- MRPS28 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 83/171 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.635); catalogued as rs763872537; called by muse, mutect2, varscan2
- PCDHGB2 | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53928720, COSV53951266; called by muse, mutect2, varscan2
- PCYT1A | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 99/224 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1041304990; called by muse, mutect2, varscan2
- SOCS1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 108/242 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.262); catalogued as rs767035200; called by muse, mutect2, varscan2
- STAG2 | c.787A>T p.R263W | Missense Mutation (SNP) | VAF 70/78 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99493130; called by muse, mutect2, varscan2
- FAM135A | c.1028G>A p.R343K (on ENST00000370479 / NM_001351599.1; = p.R326K on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- GTSF1 | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 71/182 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.369); called by muse, varscan2
- RAP2C | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- SAMD4B | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZBTB33 | c.1619A>G p.H540R | Missense Mutation (SNP) | VAF 144/155 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BOC | c.906C>T p.D302= | Silent (SNP) | VAF 74/171 reads (43%) | called by muse, mutect2, varscan2
- FAM47C | c.1248G>A p.S416= | Silent (SNP) | VAF 134/148 reads (91%) | catalogued as rs782664966, COSV100792852; called by muse, mutect2, varscan2
- PLA2G3 | c.1258C>T p.L420= | Silent (SNP) | VAF 25/38 reads (66%) | called by muse, mutect2, varscan2
- RBM10 | c.1425C>A p.P475= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- FAM189A2 | c.857-133A>G | Intron (SNP) | VAF 92/185 reads (50%) | catalogued as rs763984419; called by muse, mutect2, varscan2
